Somatic mutation profile of tumor specimen TCGA-DD-A1E9-01A (aliquot TCGA-DD-A1E9-01A-21D-A152-10) from TCGA case TCGA-DD-A1E9, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 70.7 years (25,808 days).
Specimen TCGA-DD-A1E9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 490b1b31-ebdd-4f01-84d3-2e255691c6eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A1E9-11A (Solid Tissue Normal), aliquot TCGA-DD-A1E9-11A-11D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbe139d3-dcb5-49e4-acff-f75c98766a10

The open-access MAF lists 76 somatic variants for this specimen: 51 protein-altering or splice-affecting, 19 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 19, Intron 3, Splice Region 2, In Frame Del 1, Nonsense Mutation 1, 3'UTR 1, RNA 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD12 | c.923G>C p.S308T | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.109); catalogued as COSV59288887; called by muse, mutect2, varscan2
- AKR1C1 | c.56T>G p.L19R | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66499916; called by muse, mutect2
- ALB | c.1490T>A p.V497D | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55742381; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2968C>T p.Q990* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV51857872, COSV99783581; called by muse, mutect2
- AP2A1 | c.929T>G p.L310R | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62820941; called by muse, mutect2
- ARHGAP29 | c.1777A>C p.T593P | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV53116737; called by muse, mutect2, varscan2
- BAZ2B | c.5587G>C p.E1863Q | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.211); catalogued as COSV104413720, COSV58609629; called by muse, mutect2, varscan2
- C6orf62 | c.344T>G p.L115R | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65291144; called by muse, mutect2, varscan2
- CNTN6 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs142802849; called by mutect2, varscan2
- COL28A1 | c.378A>T p.L126F | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV68084510; called by muse, mutect2, varscan2
- CYP2A13 | c.1051T>C p.Y351H | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779523596, COSV57840000; called by muse, mutect2, varscan2
- DBT | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs150934375; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ETS1 | c.111C>G p.N37K | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV67008981; called by muse, mutect2, varscan2
- FAT1 | c.5770G>A p.G1924R | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs189271562, COSV71675933, COSV71676599; called by muse, mutect2, varscan2
- FAT3 | c.12139A>T p.T4047S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV53171371; called by muse, mutect2, varscan2
- FGF6 | c.31A>G p.M11V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.138); catalogued as COSV57405223; called by muse, mutect2, varscan2
- GFOD1 | c.746T>C p.V249A | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV64955358; called by muse, varscan2
- HRNR | c.8468G>T p.S2823I | Missense Mutation (SNP) | VAF 54/534 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.694); catalogued as rs150101773, COSV64255035, COSV64262529; called by muse, mutect2
- INO80B | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs756911036, COSV51971597; called by muse, mutect2
- IWS1 | c.2059A>T p.R687W | Missense Mutation (SNP) | VAF 47/362 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54871693; called by muse, mutect2, varscan2
- KDM3A | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs200618359, COSV57217731; called by muse, mutect2, varscan2
- KIAA1217 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV64612913; called by muse, mutect2, varscan2
- KIF7 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs747191989, COSV67999408; called by muse, mutect2
- KLK3 | c.491A>G p.E164G | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV58102925; called by muse, mutect2, varscan2
- KLK9 | c.469C>T p.L157= | Splice Region (SNP) | VAF 6/85 reads (7%) | catalogued as COSV51594523; called by muse, mutect2
- LY9 | c.263C>A p.A88D | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54437699; called by muse, mutect2
- MAML2 | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV73264729; called by muse, mutect2, varscan2
- NR3C2 | c.664A>T p.S222C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.195); catalogued as rs374672844; called by muse, mutect2, varscan2
- NR4A1 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54487531; called by muse, mutect2, varscan2
- NUAK2 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1286339754, COSV65682607; called by muse, mutect2
- PCDH19 | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV55256941; called by muse, mutect2, varscan2
- PIK3R4 | c.1645G>C p.E549Q | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as COSV63243833; called by muse, mutect2, varscan2
- PLCD4 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771737211, COSV68745560; called by muse, mutect2, varscan2
- PRKAG2 | c.1280A>G p.E427G | Missense Mutation (SNP) | VAF 130/360 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV55229384; called by muse, varscan2
- PRPF8 | c.4568G>T p.R1523L | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59262529, COSV59267574; called by muse, mutect2, varscan2
- PRR16 | c.234C>A p.D78E (on ENST00000407149 / NM_001300783.2; = p.D55E on NM_016644.2) | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65405688; called by muse, mutect2, varscan2
- PTCD1 | c.582C>G p.N194K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV52867574; called by muse, mutect2, varscan2
- PZP | c.1485C>A p.I495= | Splice Region (SNP) | VAF 7/88 reads (8%) | catalogued as COSV54370149; called by muse, mutect2
- RBFOX2 | c.685G>A p.E229K (on ENST00000438146 / NM_001349995.2; = p.E159K on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV53263881; called by muse, mutect2, varscan2
- RYR2 | c.10933G>A p.A3645T | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.063); catalogued as rs1558304228, COSV63658420, COSV63712367; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPINA1 | c.611_612del p.T204Sfs*11 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | catalogued as rs921982028; called by pindel, varscan2
- SLX4 | c.4681A>G p.T1561A | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV53568441; called by muse, mutect2, varscan2
- SSH3 | c.1670G>T p.S557I | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.083); catalogued as COSV57386687; called by muse, mutect2, varscan2
- TDRD12 | c.383A>G p.Y128C | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs775908730, COSV70015874; called by muse, mutect2, varscan2
- TRAPPC10 | c.2470A>T p.S824C | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52381357; called by muse, mutect2, varscan2
- TRAPPC8 | c.2306T>C p.L769P | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51977152; called by muse, mutect2, varscan2
- UBR5 | c.8111C>T p.A2704V | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as COSV55299747; called by muse, mutect2
- UGT8 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 88/324 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60420776; called by muse, mutect2, varscan2
- USP5 | c.2458G>A p.V820I (on ENST00000229268 / NM_001098536.2; = p.V797I on NM_003481.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); catalogued as rs782621306, COSV57540253; called by muse, mutect2, varscan2
- WHAMM | c.1358A>G p.D453G | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1483329888, COSV54499652; called by muse, mutect2, varscan2
- MSH2 | c.2591_2617del p.D864_C873delinsG | In Frame Del (DEL) | VAF 22/158 reads (14%) | called by mutect2, pindel
- ADAMTSL4 | c.2694T>C p.P898= | Silent (SNP) | VAF 41/82 reads (50%) | catalogued as COSV55007312; called by muse, mutect2, varscan2
- AP2A1 | c.927C>T p.I309= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV62820932; called by muse, mutect2
- CLEC19A | c.243C>T p.A81= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV71854344; called by muse, mutect2, varscan2
- COBL | c.3276G>A p.K1092= | Silent (SNP) | VAF 97/298 reads (33%) | catalogued as COSV54357743; called by muse, mutect2, varscan2
- DARS2 | c.1701G>A p.L567= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV53409009; called by muse, mutect2
- FAT3 | c.7851C>T p.H2617= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV53171356; called by muse, mutect2, varscan2
- FDPS | c.1026A>G p.Q342= | Silent (SNP) | VAF 118/199 reads (59%) | catalogued as COSV52742534; called by muse, mutect2, varscan2
- HAS2 | c.504G>A p.S168= | Silent (SNP) | VAF 163/284 reads (57%) | catalogued as rs1251869360, COSV58267082; called by muse, mutect2, varscan2
- KCNQ1 | c.1938C>T p.G646= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs184844767, COSV50129213; called by muse, mutect2, varscan2
- KRT86 | c.1134C>A p.A378= | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as COSV53293665, COSV53294253; called by muse, mutect2, varscan2
- LRFN2 | c.564C>T p.I188= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs756661889, COSV57834340; called by muse, mutect2, varscan2
- OLFM4 | c.600G>A p.K200= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV54580395; called by muse, mutect2, varscan2
- PABPN1 | c.810C>T p.T270= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV53730326; called by muse, mutect2
- PCLO | c.3642C>T p.L1214= | Silent (SNP) | VAF 303/779 reads (39%) | catalogued as COSV61619583, COSV61664490; called by muse, mutect2, varscan2
- PLEKHH1 | c.1722G>A p.L574= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV61287653; called by muse, mutect2, varscan2
- PLXND1 | c.3921G>T p.T1307= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV60719261; called by muse, mutect2, varscan2
- USP38 | c.642G>A p.L214= | Silent (SNP) | VAF 31/114 reads (27%) | catalogued as COSV61027369; called by muse, mutect2, varscan2
- WFDC8 | c.492G>A p.E164= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV51491847; called by muse, mutect2, varscan2
- XRCC6 | c.840T>A p.A280= | Silent (SNP) | VAF 43/145 reads (30%) | catalogued as COSV63158805; called by muse, mutect2, varscan2
- GLMP | c.799-179G>T | Intron (SNP) | VAF 44/86 reads (51%) | called by muse, mutect2, varscan2
- HP | c.5+23T>C | Intron (SNP) | VAF 70/443 reads (16%) | called by muse, mutect2, varscan2
- ITPKB | c.1932+27655A>G | Intron (SNP) | VAF 28/373 reads (8%) | catalogued as COSV99684828; called by muse, mutect2
- RNF182 | c.*64A>G | 3'UTR (SNP) | VAF 38/164 reads (23%) | catalogued as COSV101337934; called by muse, mutect2, varscan2
- SSPOP | n.9184G>T | RNA (SNP) | VAF 5/54 reads (9%) | catalogued as COSV100947716; called by muse, mutect2
- TATDN1 | c.-14C>A | 5'UTR (SNP) | VAF 27/52 reads (52%) | catalogued as rs778161404, COSV99412914; called by muse, mutect2, varscan2
